Gene-level copy-number profile of tumor specimen TCGA-IB-7651-01A from TCGA case TCGA-IB-7651, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.6 years (23,580 days).
Specimen TCGA-IB-7651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.934c5ea2-9ace-453c-8e08-934c857ceda7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-7651-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d8ee62e4-3fa4-4c24-b826-9f0ed38f7ed5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,950; copy number 1: 3,607; copy number 2: 45,623; copy number 3: 7,866; copy number 4: 218; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-7651-01A-11D-2153-01): tumor purity 0.39, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,424,384–19,424,671, 1 gene: RN7SL277P.
- chr6:30,414,715–30,494,194, 6 genes: MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E.
- chr8:72,019,917–72,075,584, 1 gene: TRPA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:93,309,669–93,311,063, 1 gene, copy number 9: AL160159.1.

Autosomal genes at a single copy (total copy number 1): 3,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
